Gene-level copy-number profile of tumor specimen C3L-06707-05 from CPTAC case C3L-06707, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 52.5 years (19,168 days).
Specimen C3L-06707-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6c078712-16f2-41f4-9ef9-907b70474164.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06707-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/957acd12-ec68-4c47-b241-17f282c52b0c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 517; copy number 1: 3,343; copy number 2: 23,381; copy number 3: 21,779; copy number 4: 3,693; copy number 5: 4,681; copy number 6: 496; copy number 7: 702; copy number 8: 106; copy number 9: 63; copy number 11: 106; copy number 15: 2; copy number 19: 2; copy number 26: 15; copy number 31: 5; copy number 37: 8.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:78,355,529–78,355,834, 1 gene (within-gene range 0–2): LSM3P5.
- chr19:43,153,279–43,248,646, 4 genes (within-gene range 0–2): AC005392.1, PSG5, PSG4, CEACAMP10.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,186 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–686,673, 35 genes, copy number 5 (within-gene range 2–5): DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, RNU6-1100P, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, OR4F16.
- chr1:150,887,136–151,267,479, 25 genes, copy number 6: CTXND2, CYCSP51, SETDB1, CERS2, AL590133.2, AL590133.1, ANXA9, MINDY1, PRUNE1, RNU6-884P, BNIPL, C1orf56, CDC42SE1, MLLT11, GABPB2, RPS29P29, AL592424.1, SEMA6C, TNFAIP8L2, SCNM1, LYSMD1, TMOD4, VPS72, PIP5K1A, PSMD4.
- chr1:155,230,975–156,295,689, 58 genes, copy number 5: MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1, ASH1L, MIR555, RNU6-106P, ASH1L-IT1, RNU6-1297P, POU5F1P4, ASH1L-AS1, AL353807.4, DAP3P1, AL353807.1, AL353807.2, MSTO1, AL353807.3, AL353807.5, YY1AP1, DAP3, AL162734.1, MSTO2P, GON4L, AL139128.1, SYT11, RIT1, KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1, ARHGEF2-AS1, AL355388.2, SSR2, UBQLN4, LAMTOR2, RAB25, MEX3A, LMNA, SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5, TMEM79, GLMP.
- chr1:219,685,427–221,840,717, 45 genes, copy number 5–6: SLC30A10, RNA5SP76, U3, EPRS1, BPNT1, IARS2, MIR215, MIR194-1, RPS15AP12, RAB3GAP2, MIR664A, SNORA36B, SNX2P1, KF455155.1, MORF4L1P1, AURKAP1, XRCC6P3, AL451081.2, AL451081.1, AC096644.3, AC096644.2, AC096644.1, PRELID3BP1, LINC02779, MARK1, RN7SL464P, HDAC1P2, C1orf115, MTARC2, MTARC1, AL445423.3, RNU6ATAC35P, AL445423.2, AL445423.1, LINC01352, HLX-AS1, HLX, AL445466.1, LINC02817, AL360013.2, AL360013.3, AL360013.1, DUSP10, LINC01655, RNU6-403P.
- chr1:223,181,144–224,779,335, 38 genes, copy number 5: AL359979.1, SUSD4, RNU4-57P, CCDC185, CAPN8, SNRPEP10, RNU6-1248P, CAPN2, TP53BP2, PHBP11, ACTBP11, CICP5, GTF2IP20, RNU6-1319P, AC138393.1, AC138393.3, AC138393.2, RN7SKP49, FBXO28, AC092809.3, DEGS1, SNORA72, AC092809.2, AC092809.4, NVL, MIR320B2, AC092809.1, RNU6-1008P, CNIH4, WDR26, MIR4742, CNIH3, AKR1B1P1, CNIH3-AS2, DNAJB6P6, AL596330.1, CNIH3-AS1, LINC02813.
- chr1:228,687,415–232,041,272, 72 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:244,835,616–245,709,432, 15 genes, copy number 5 (within-gene range 4–5): COX20, HNRNPU, BX323046.1, RN7SKP55, RNU6-947P, AL356512.1, EFCAB2, RNU6-1089P, RNU6-999P, AL589763.1, RNU1-132P, KIF26B, KIF26B-AS1, DNAJC19P8, AC104462.2.
- chr7:37,032–48,927,454, 843 genes, copy number 5 (broad region; genes not listed).
- chr7:71,132,144–76,516,522, 148 genes, copy number 5 (within-gene range 5–7) (broad region; genes not listed).
- chr7:76,818,377–142,802,748, 1,190 genes, copy number 5–6 (broad region; genes not listed).
- chr8:12,341,426–12,400,366, 6 genes, copy number 6–7: DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A.
- chr8:46,028,804–145,066,685, 1,494 genes, copy number 5–8 (within-gene range 5–9) (broad region; genes not listed).
- chr9:12,134–179,147, 11 genes, copy number 5: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1.
- chr9:63,832,127–68,531,061, 88 genes, copy number 5 (broad region; genes not listed).
- chr11:69,641,156–80,957,634, 314 genes, copy number 5–11 (broad region; genes not listed).
- chr11:127,021,736–127,408,148, 5 genes, copy number 8–15 (within-gene range 2–15): AP001993.1, AP003121.1, LINC02712, RN7SKP121, RN7SKP279.
- chr14:18,333,726–18,343,144, 2 genes, copy number 5: CR383658.1, RNU6-458P.
- chr16:7,726,841–9,676,843, 37 genes, copy number 6–7: AC005774.1, AC093515.1, AC018767.2, LINC02152, AC018767.3, AC018767.1, AC074052.1, AC074052.2, TMEM114, METTL22, AC007224.2, ABAT, RN7SL743P, RNU7-63P, AC007224.1, TMEM186, PMM2, AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4, USP7, AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119, LINC02177, AC012178.1, LINC01177, LINC01195, AC007221.1, RNA5SP403, RNA5SP404, AC007218.1.
- chr16:11,242,653–11,976,643, 34 genes, copy number 5: HNRNPCP4, RMI2, SOCS1, TNP2, PRM3, AC009121.1, PRM2, PRM1, AC009121.4, MIR548H2, Y_RNA, AC009121.3, AC009121.2, AC099489.1, AC099489.2, AC099489.3, LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4, RSL1D1, AC007216.4, GSPT1, AC007216.3, COX6CP1, AC007216.2, AC007216.5, NPIPB2, TNFRSF17, UBL5P4.
- chr16:17,540,331–17,540,985, 1 gene, copy number 6: AC109495.1.
- chr16:19,285,731–19,499,113, 6 genes, copy number 5 (within-gene range 3–5): CLEC19A, AC130456.1, AC130456.2, AC130456.7, TMC5, AC130456.4.
- chr16:24,610,209–25,021,023, 6 genes, copy number 6: TNRC6A, LINC01567, AC008731.1, SLC5A11, ARHGAP17, AC133552.1.
- chr16:29,380,242–31,453,493, 182 genes, copy number 6–8 (broad region; genes not listed).
- chr16:34,941,977–46,621,379, 83 genes, copy number 5–37 (broad region; genes not listed).
- chr16:74,612,596–75,761,872, 47 genes, copy number 5: HSPE1P7, RFWD3, TMPOP2, MLKL, FA2H, AC009132.1, WDR59, ZNRF1, AC099508.1, LDHD, AC099508.2, ZFP1, AC009078.1, CTRB2, CTRB1, AC009078.2, BCAR1, AC009078.3, RNU6-758P, CFDP1, AC009054.1, AC009054.2, AC009163.2, AC009163.5, AC009163.7, TMEM170A, AC009163.4, CHST6, AC009163.1, AC009163.6, TMEM231P1, AC009163.3, CHST5, TMEM231, AC025287.1, AC025287.2, GABARAPL2, AC025287.3, ADAT1, KARS1, AC025287.5, TERF2IP, AC025287.4, DUXB, RN7SL520P, ATP5PBP7, CPHXL.
- chr20:87,250–64,327,972, 1,401 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 999. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
